Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A2FF, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A2FF-01A (Primary Tumor).

[page 1 of 4]
Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Surgical Report

Requested by:

100-0-3

carcinoma, infiltrating lobular, nos 8520/3

Site: breast, nos C50.9 w 6/10/11

SEE REPORT

ADDENDUM INFORMATION

PROCEDURE DATE:

==== ADDENDUM REPORT #2; COMMENT: =====

The panel of breast cancer markers was performed at using material from block B/BPC3. The results are summarized in part B/BPC line 10. I have seen the results and concur with the findings as stated.

T:

==== ADDENDUM REPORT #2; DIAGNOSIS: =====

A/APC & C. SEE ORIGINAL DIAGNOSES

B/BPC. RIGHT BREAST MASS, EXCISION:

1 - 9. SEE ORIGINAL DIAGNOSES

10. ANCILLARY STUDIES: BREAST CANCER PROGNOSTIC PANEL:

ASSAY RESULTS

Test Name	Staining Intensity	Percent Positive	Prognostic Significance
Assay Type	Average	Average	
ER	N/A	37%	Favorable
PR	N/A	71%	Favorable
HER-2/neu	1.7	N/A	Normal Limit
Ki-67	N/A	18%	Borderline

REFERENCE RANGES

Test	Favorable	Borderline	Unfavorable
ER	>5%		<5%
PR	>5%		<5%
Her2/neu	<2.0		>2.0
Ki-67	<10%	>10% - <20%	>20%

11. SEE ORIGINAL DIAGNOSIS

A-MALIGNANT

T:

(Electronic Signature)

==== ADDENDUM REPORT #1; COMMENT: =====

An immunostain for E-cadherin utilizing material from block A is entirely negative. This supports the light microscopic diagnosis of lobular carcinoma.

==== ADDENDUM REPORT #1; DIAGNOSIS: =====

PENDING BREAST CANCER PANEL STUDIES ON B/BPC-3

A & APC. SENTINEL LYMPH NODE, RIGHT AXILLA: METASTATIC LOBULAR CARCINOMA

[page 2 of 4]
Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient [REDACTED] Requested by: [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name :Surgical Report

PRESENT IN ONE LYMPH NODE; NEGATIVE E-CADHERIN IMMUNOSTAIN
B & BPC. RIGHT BREAST MASS, EXCISION:
1. TUMOR TYPE: INFILTRATING LOBULAR CARCINOMA, SEE COMMENT
BELOW
2 - 11. SEE ORIGINAL DIAGNOSES
C. SEE ORIGINAL DIAGNOSIS
COMMENT: As noted, breast cancer marker studies will be performed on B/BPC-3.
A-MALIGNANT

(Electronic Signature)

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

- A. ~~RIGHT~~ AXILLARY SENTINEL LYMPH NODE, APC
- B. RIGHT BREAST BIOPSY, BPC
- C. AXILLARY CONTENTS

==== PRE-OPERATIVE DIAGNOSIS: =====

Right breast cancer

==== POST-OPERATIVE DIAGNOSIS: =====

Same

==== CLINICAL INFORMATION: =====

Invasive ductal carcinoma in retroareolar space; right breast mass

==== INTRAOPERATIVE CONSULTATION: =====

APC DIAGNOSIS: "Metastatic carcinoma," by Dr.

BPC DIAGNOSIS: "Tissue obtained for genomics," by

T:

==== GROSS DESCRIPTION: =====

A. Received in formalin is an irregular tan-gray nodule, measuring 2.0 x 1.6 x 0.5 cm. The specimen is bisected and entirely submitted in one cassette.
APC. Received in formalin is an irregular portion of tan-gray soft tissue, measuring 1.5 x 1.5 x 0.2 cm. The specimen is entirely submitted in one cassette.
B/BPC. Received in formalin is a portion of tan-yellow fibrofatty tissue, measuring 6.8 cm from medial to lateral, 6.7 cm from superior to inferior, and 4.8 cm from anterior to posterior. The specimen is oriented as follows: short stitch - superior; long stitch - lateral. The anterior aspect is covered by skin, measuring 5.0 x 3.0 x 0.2 cm. Centrally located on the skin surface is the nipple, measuring 1.0 x 1.0 x 0.8 cm. The cut surface of the nipple is tan and unremarkable. The specimen is inked as follows: superior - blue; inferior - green; medial - red; lateral - yellow; anterior - orange; posterior - black. Sectioning from medial to lateral reveals a poorly-defined tan-gray

[page 3 of 4]
Requested by [REDACTED]
Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider :
Report Name :Surgical Report

tumor mass, measuring approximately 5.0 x 3.0 x 1.5 cm. This area is diffusely covered with blue radiographic dye. The cut surface is firm and gritty. The tumor mass blends into the adjacent thick fibrotic tissue. The tumor comes to within 1.0 cm of the medial margin, 0.2 cm of the lateral margin, 2.0 cm of the superior margin, 0.7 cm of the inferior margin, 1.5 cm of the skin and nipple, and abuts the posterior margin. The remaining cut surface is composed of approximately 50% adipose tissue and 50% fibrous tissue. A biopsy cavity or metallic clip is not found. Representative sections are sequentially submitted, from medial to lateral, in six cassettes as follows: cassette 1 - medial margin; cassette 2 - nipple with anterior aspect; cassette 3 - tumor mass with closest posterior margin; cassette 4 - tumor mass with superior margin; cassette 5 - tumor mass with inferior margin; cassette 6 - tumor mass with lateral margin.

C. Received in formalin is an irregular portion of tan-yellow fatty tissue, measuring 5 x 4 x 2 cm. Six possible lymph nodes, ranging from 0.4 x 0.3 x 0.3 cm to 1.5 x 1.0 x 0.8 cm, are identified. The cut surface of the largest lymph node shows foci of tan-gray discoloration. The lymph nodes are entirely submitted in four cassettes as follows: cassette 1 - one intact and one bisected lymph node; cassette 2 - one lymph node; cassette 3 - two bisected lymph nodes (one inked black); cassette 4 - largest lymph node.

==== MICROSCOPIC DESCRIPTION: =====

A & APC. One slide is examined for each portion of the case. Both slides demonstrate extensive lymph node involvement by poorly differentiated carcinoma. Because of the obvious nature of this finding, it will not be necessary to perform a cytokeratin stain.

B/BPC. Six slides are examined. Slide 1 show benign breast tissue without evidence of tumor involvement. The red inked medial margin is free of tumor. Slide 2 shows tissue from the region of the nipple. There is patchy ductal hyperplasia and no evidence of Paget's disease is evident. Slide 3 shows extensive infiltrating carcinoma with a pattern most suggestive of lobular carcinoma with periductal targetoid-like areas and numerous foci of "Indian file" arrangement. On this slide, tumor is present approximately 0.1 mm to the black inked posterior surface. The tumor shows no evidence of tubular formation (tubules = 3). Nuclei exhibit occasional prominent nucleoli and these seem to be multiple in some scattered foci. In the most mitotically active areas of tumor, approximately eighteen to nineteen mitoses are present within ten high power field (mitoses = 2). The Nottingham score of this lesion is therefore 7 (3+3+2), making this a grade II lesion. Slide 4 shows no evidence of malignancy. Slide 5 shows infiltrating carcinoma with a clear inferior green inked margin. Changes consistent with a prior biopsy site are also present. No tumor is seen on slide 6.

C. Four slides are examined. These show six lymph nodes. Positive lymph

[page 4 of 4]
Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name : Surgical Report

Requested by:

nodes are present on C1 and C3 for a total of two positive lymph nodes out of six. Including the sentinel lymph node in part A/APC, a total of three out of seven lymph nodes are positive for metastatic carcinoma.

----- FINAL DIAGNOSIS: -----

(PRELIMINARY - PENDING BREAST CANCER PANEL STUDIES TO BE PERFORMED ON B/BPC-3)

A & APC. SENTINEL LYMPH NODE, RIGHT AXILLA: METASTATIC CARCINOMA PRESENT IN ONE LYMPH NODE (1/1)

B/BPC. RIGHT BREAST MASS, EXCISION:

1. TUMOR TYPE: INFILTRATING CARCINOMA MOST LIKELY LOBULAR CARCINOMA, SEE COMMENT BELOW
2. NOTTINGHAM PROGNOSTIC INDEX: 7 (3+2+2), GRADE II
3. MAXIMUM INVASIVE TUMOR SIZE: GROSSLY ESTIMATED AT APPROXIMATELY 5 CM (pT2)
4. PERCENT DCIS: ZERO
5. LVI: NOT IDENTIFIED
6. DISTANCE TO CLOSEST MARGIN: APPROXIMATELY 0.1 MM TO POSTERIOR INKED MARGIN (B/BPC-3 SLIDE)
7. MICROCALCIFICATIONS: NOT IDENTIFIED
8. LYMPH NODES: SEE PART C BELOW
9. TNM STATUS: pT2,N1,MX
10. ANCILLARY STUDIES: TO FOLLOW ON BLOCK B/BPC-3
11. OTHER FINDINGS:

SEE REPORT

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE:

----- FINAL DIAGNOSIS: -----

- CHANGES CONSISTENT WITH PRIOR BIOPSY
- FOCAL FIBROCYSTIC CHANGES OF REMAINING BREAST PARENCHYMA
- C. AXILLARY CONTENTS, RIGHT: METASTATIC CARCINOMA IDENTIFIED IN TWO OF SIX AXILLARY LYMPH NODES, TOTAL 3/7 INCLUDING SENTINEL LYMPH NODE, AS ABOVE

COMMENT: As noted, breast cancer marker studies will be performed on B/BPC-3; in addition to confirm the lobular nature of this tumor, I will order an E-Cadherin immunostain on block A.

A-MALIGNANT

(Electronic Signature)

DATE AND TIME OF REPORT:

Source: NCI Genomic Data Commons file 6d65897b-acdf-492b-af6b-9d46ba05d760 (TCGA-AC-A2FF.E6897E14-465A-486A-A6AD-FCFED21629F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).